TARGET case TARGET-50-PAKJVW — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63a8235c-cf7a-5295-b58e-9542ad65aa40

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 2.3 years (845 days); Year of diagnosis: 2000; Days to last follow up: 3,120 days (8.5 years); Pediatric kidney staging: Tumor biopsied only at diagnosis, no distant metastasis; Wilms tumor histologic subtype: Favorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (2 entries)
- Days to follow up: 467 days (1.3 years); Days to first event: 467 days (1.3 years); First event: Relapse.
- Days to follow up: 3,120 days (8.5 years); Year of follow up: 2010.

Biospecimens (1 sample)
- Sample TARGET-50-PAKJVW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3120
- Stage: IIIB
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: FHWT
